CCDI case PBBRLD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/35e25b3f-bfae-4d29-8088-2f6f54a5b24a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.9 years (5,061 days).

Biospecimens (3 samples)
- Sample 0DF07H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF07P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF07Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
